Surgical pathology report (de-identified scan), TCGA case TCGA-29-1774, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1774-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1774

Surg Path

CLINICAL HISTORY:

[REDACTED] = malignant neoplasm ovary, [REDACTED] = abdominal/pelvic swelling NOS
Per E-browser: [REDACTED] with carcinomatosis that is likely ovarian.

GROSS EXAMINATION:

A. "Left tube and ovary (AF1)", received fresh for frozen consultation is a 17 gm adnexal specimen with a 2 x 1.5 x 0.5 cm ovary with a cerebriform surface from which arise multiple foci of tan papillary excrescences as well as a 4.5 x 4 x 2 cm multiloculated cyst which has previously been opened in the operating room. The cyst wall has a 2 x 1.5 x 1.5 cm area of tan papillary excrescences as well as multiple foci of excrescences within the inner cyst wall. There is no gross invasion of the tan, fibrous ovarian parenchyma by the aforementioned excrescences. A representative section of cyst wall with excrescences is frozen as AF1. The adjacent fallopian tube (4 cm long x 0.5 cm diameter) exhibits a serosal surface with diffuse adhesions and an unremarkable patent lumen.

BLOCK SUMMARY:

A1- frozen section remnant AF1, representative cyst wall excrescences
A2- sections of ovarian cyst and ovary
A3- additional sections of ovary and fallopian tube

B. "Right ovary and tube", received fresh and placed in formalin is a 65 gm 8 x 7.5 x 3 cm aggregate of pink-tan tissue received as multiple fragments. The fragments are grossly consistent with cyst wall, which exhibits a dusky serosal surface with diffuse adhesions and an inner surface remarkable for multiple soft, tan papillary excrescences. No ovary or fallopian tube is identified within the submitted fragments. Representative sections of tissue are submitted in blocks B1-B6.

C. "Omentum", received fresh and placed in formalin is a 20.5 x 14.5 x 4 cm aggregate of abnormally firm fibroadipose tissue with a tan-yellow, fleshy cut surface. Representative sections are submitted in blocks C1-C3.

INTRA OPERATIVE CONSULTATION:

A. "Left tube and ovary": AF1- carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Bilateral salpingo-oophorectomy, peritoneal biopsy

PATHOLOGIC STAGE (AJCC 6th Edition): pT3b pNx pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] required for accreditation by the [REDACTED] stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

[page 2 of 2]
TCGA-29-1774

DIAGNOSIS:

A. "LEFT OVARY AND FALLOPIAN TUBE (AF1)":

LEFT OVARY:

TYPE: PAPILLARY SEROUS ADENOCARCINOMA

FIGO GRADE: 3

TUMOR SIZE: 4.5 X 4 X 2 CM.

WEIGHT: 17 GRAMS

Serosa: SURFACE GROWTH PRESENT

LEFT FALLOPIAN TUBE: POSITIVE FOR SEROUS ADENOCARCINOMA

B. "RIGHT OVARY AND FALLOPIAN TUBE":

RIGHT OVARY:

TYPE: PAPILLARY SEROUS ADENOCARCINOMA

FIGO GRADE: 3

TUMOR SIZE: 8 X 7.5 X 3 CM.

WEIGHT: 65 GRAMS

Serosa: POSITIVE

RIGHT FALLOPIAN TUBE: POSITIVE FOR TUMOR.

C. "OMENTUM" (BIOPSY):

METASTATIC PAPILLARY SEROUS ADENOCARCINOMA.

COMMENT: Immunostains of the tumor in part A are positive for CK7, BerEP4, and WT1, and are negative for CK20, CDX2, and calretinin, consistent with a primary serous carcinoma of the ovary.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file c56671f9-8974-4e31-a4b4-39b7825de973 (TCGA-29-1774.8D8DD2F0-09D8-42A2-84E0-4209E45E2330.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).